TCGA case TCGA-UB-A7MB — Liver Hepatocellular Carcinoma (TCGA-LIHC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Liver and intrahepatic bile ducts; Tissue source site: UCSF. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/af1e56af-410c-4cad-a4e8-1c6937f1a350

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 24 years; Vital status: Alive.

Diagnoses (2)
1. Hepatocellular carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8170/3; ICD-10 code: C22.0; Tissue or organ of origin: Liver; Site of resection or biopsy: Liver; Classification of tumor: primary; Age at diagnosis: 24.5 years (8,951 days); Year of diagnosis: 2013; AJCC staging edition: 7th; AJCC pathologic T: T2; AJCC pathologic N: NX; AJCC pathologic M: MX; AJCC pathologic stage: Stage II; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Child pugh classification: A; Ishak fibrosis score: 0 - No Fibrosis.
   Pathology details: Consistent pathology review: Yes; Vascular invasion present: Yes; Vascular invasion type: Micro.
   Treatment given: Treatment type: Chemoembolization; Therapeutic agents: Doxorubicin; Days to treatment start: 85 days; Embolic agent: Plastic Beads.
   Treatment given: Treatment type: Chemoembolization; Therapeutic agents: Doxorubicin; Days to treatment start: 112 days; Embolic agent: Plastic Beads.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Sorafenib; Days to treatment start: 123 days; Days to treatment end: 168 days; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Clinical Trial Agent; Days to treatment start: 187 days; Days to treatment end: 382 days (1.0 years); Treatment outcome: Stable Disease; Clinical trial indicator: Yes.
   Treatment given: Treatment type: Ablation, Radiofrequency; Days to treatment start: 365 days (1.0 years); Number of cycles: 1; Lesions treated number: 1.
   Treatment given: Treatment type: Chemoembolization; Therapeutic agents: Doxorubicin + Mitomycin; Days to treatment start: 390 days (1.1 years); Embolic agent: Other.
   Treatment given: Treatment type: Radioembolization; Days to treatment start: 417 days (1.1 years); Embolic agent: Y-90 Therasphere.
   Treatment given: Treatment type: Chemoembolization; Therapeutic agents: Doxorubicin; Days to treatment start: 428 days (1.2 years); Embolic agent: Plastic Beads.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil + Oxaliplatin; Days to treatment start: 480 days (1.3 years); Days to treatment end: 510 days (1.4 years); Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Clinical Trial Agent; Days to treatment start: 525 days (1.4 years); Treatment outcome: Treatment Ongoing; Clinical trial indicator: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Recurrence of diagnosis 1 (Hepatocellular carcinoma, NOS), site: Liver. Age at diagnosis: 24.6 years (8,999 days); Days to diagnosis: 48 days; Prior treatment: Yes.
   Treatment given: Treatment type: Ablation or Embolization, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Organ Transplantation to Liver, for recurrent disease; Radiation Therapy, NOS, for recurrent disease; Surgery, NOS, for recurrent disease.

Follow-up (4 entries)
- Day 48 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Local; Progression or recurrence anatomic site: Liver; Days to recurrence: 48 days.
- Days to follow up: 526 days (1.4 years); Disease response: With Tumor.
- Days to follow up: 601 days (1.6 years); Disease response: With Tumor.
- ECOG performance status: 0.

Molecular and laboratory tests
- Creatinine 0.4 mg/dL [Blood test normal range lower: 0.7; Blood test normal range upper: 1.2].
- Platelets 583 (unit not recorded by GDC) [Blood test normal range lower: 140; Blood test normal range upper: 450].
- Alpha Fetoprotein 1865 ng/mL [Blood test normal range lower: 0; Blood test normal range upper: 8].
- Total Bilirubin 0.4 mg/dL [Blood test normal range lower: 0.2; Blood test normal range upper: 1.3].
- Prothrombin time (INR, as labelled on the TCGA clinical form) 1 [Blood test normal range lower: 0.9; Blood test normal range upper: 1.2].
- Albumin 3.1 (unit not recorded on the TCGA source form) [Blood test normal range lower: 3.5; Blood test normal range upper: 4.8].

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Viral hepatitis serology tests: Hepatitis B Surface Antigen / HBV Core Antibody / Hepatitis C Antibody.
- Timepoint category: Initial Diagnosis; Weight: 62 kg; Height: 180 cm; BMI: 19.1.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-UB-A7MB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 140 mg.
  Slide TCGA-UB-A7MB-01A-01-TS1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-UB-A7MB-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-UB-A7MB-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Tumor status: With tumor; Histologic diagnosis: Hepatocellular Carcinoma; Definitive surgical procedure: Lobectomy.
- History hepato carcinoma risk factors: No History of Primary Risk Factors.
- Viral hepatitis serologies: Viral hepatitis serology: Hepatitis  C Antibody; Viral hepatitis serology: Hepatitis B Surface Antigen; Viral hepatitis serology: HBV Core Antibody.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor.
- Drug treatment 1: Treatment best response: Clinical Progressive Disease.
- Drug treatment 2: Clinical trial drug classification: TORC1/2 inhibitor.
- Drug treatment 3: Pharmaceutical therapy drug name: 5-fluorouracil; Treatment best response: Clinical Progressive Disease.
- Drug treatment 5: Clinical trial drug classification: Imid.
- Ablations, Ablation 1, Ablation treatments: Ablation performed indicator: No.
- Ablations, Ablation 1, Embolization treatments: Embolization performed indicator: Yes.
- Ablations, Ablation 1, Embolization treatments, Embolization treatment: Embolization therapy drug name: Mitomycin C; Embolizing agent utilized: Ethiodol.
- Ablations, Ablation 2, Ablation treatments: Ablation performed indicator: Yes.
- Ablations, Ablation 2, Ablation treatments, Ablation treatment: Ablation type: Radiofrequency Ablation; Treatment cycles count: 1; Lesions count: 1.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 601 days; disease-specific survival: no event (censored), 601 days; disease-free interval: event (new tumor event after initially disease-free), 48 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 48 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-UB-A7MB-01A-11D-A33P-01): tumor purity 0.93, ploidy 1.92, whole-genome doublings 0.
